Gene-level copy-number profile of tumor specimen TCGA-QK-A8Z9-01B from TCGA case TCGA-QK-A8Z9, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 56.0 years (20,471 days).
Specimen TCGA-QK-A8Z9-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.5b190468-8a0b-4bf9-a20f-ea4fda054dc5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QK-A8Z9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d6ec42b7-ad02-43b7-b0c6-46f29771522a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 3,531; copy number 2: 19,473; copy number 3: 19,533; copy number 4: 15,316; copy number 5: 1,364; copy number 6: 150; copy number 7: 48; copy number 8: 96; copy number 9: 4; copy number 10: 3; copy number 11: 10; copy number 12: 30; copy number 13: 70; copy number 14: 18; copy number 15: 2; copy number 16: 42; copy number 17: 8; copy number 21: 2; copy number 23: 8; copy number 26: 79; copy number 29: 2; copy number 33: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-QK-A8Z9-01B-11D-A390-01): tumor purity 0.41, ploidy 2.98, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:25,697,076–25,878,487, 3 genes (within-gene range 0–2): Y_RNA, ASXL2, TPM3P7.
- chr4:90,838,903–90,839,037, 1 gene: TMSB4XP8.
- chr8:3,700,492–3,700,628, 1 gene: RNA5SP251.
- chr9:21,966,929–22,128,103, 8 genes (within-gene range 0–4): CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr16:80,597,907–80,804,598, 3 genes (within-gene range 0–2): CDYL2, AC092332.1, AC099313.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 431 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:157,400,927–158,177,755, 20 genes, copy number 11–16: AL732406.1, AL353899.1, FCRL5, FCRL4, AL135929.2, AL135929.1, FCRL3, AL356276.1, AL356276.2, VDAC1P9, FCRL2, FCRL1, CD5L, MRPS21P2, AL139010.1, KIRREL1, KIRREL1-IT1, SMIM42, LINC01704, ELL2P1.
- chr4:138,560,704–138,803,567, 3 genes, copy number 8: AC098859.1, AC098859.2, AC093766.1.
- chr4:140,756,528–141,576,077, 9 genes, copy number 8: AC096733.2, Y_RNA, RNF150, ZNF330, AC107220.1, LINC02432, AC097504.1, AC097504.2, LINC02276.
- chr4:147,344,629–147,344,717, 1 gene, copy number 7: MIR548G.
- chr4:147,480,917–147,544,954, 1 gene, copy number 7 (within-gene range 2–7): EDNRA.
- chr4:147,506,091–148,444,698, 12 genes, copy number 7 (within-gene range 3–7): GTF2F2P1, LINC02507, AC093835.1, TMEM184C, PRMT9, ARHGAP10, RNA5SP165, MIR4799, RN7SL254P, AC115621.1, NR3C2, AC069272.1.
- chr4:149,147,793–149,278,123, 2 genes, copy number 8: LINC02430, LINC02355.
- chr4:149,377,257–149,380,107, 1 gene, copy number 8: AC108168.1.
- chr4:153,633,692–153,789,083, 7 genes, copy number 7: AC106865.2, AC106865.1, WDR45P1, TLR2, RNF175, AC020703.1, SFRP2.
- chr4:154,754,756–154,828,813, 5 genes, copy number 8: AC009567.1, AC009567.2, RBM46, RNU2-66P, RNU2-44P.
- chr4:155,666,726–156,006,988, 7 genes, copy number 8: GUCY1A1, AC104083.1, GUCY1B1, ASIC5, TDO2, CTSO, FTH1P21.
- chr4:159,375,099–159,401,246, 2 genes, copy number 9: AC074344.1, AC074344.2.
- chr4:162,022,733–162,047,567, 1 gene, copy number 7: AC023136.1.
- chr4:164,188,311–164,197,711, 2 genes, copy number 9: AC105250.1, ANP32C.
- chr4:165,873,237–166,526,119, 4 genes, copy number 8 (within-gene range 3–8): TLL1, RNA5SP170, Y_RNA, AC097487.1.
- chr4:168,170,097–168,537,786, 4 genes, copy number 7: AC068989.1, DDX60, DDX60L, AC079926.1.
- chr4:168,598,240–168,648,587, 2 genes, copy number 7: BTF3L4P4, PALLD-AS1.
- chr4:170,891,467–171,114,581, 4 genes, copy number 8: RNU6ATAC13P, AC034159.2, LINC02431, AC034159.1.
- chr4:173,699,082–174,001,488, 3 genes, copy number 10 (within-gene range 3–10): LINC02269, AC106895.1, AC106895.2.
- chr4:175,038,080–176,014,417, 10 genes, copy number 8 (within-gene range 4–8): AC022325.2, AC095050.2, AC095050.1, AC131094.1, TSEN2P1, ADAM20P2, GPM6A, AC097537.1, AC110794.1, MARK2P4.
- chr4:178,406,695–178,406,830, 1 gene, copy number 8: RNA5SP173.
- chr4:179,069,437–179,069,594, 1 gene, copy number 8: AC018710.1.
- chr4:180,731,164–181,159,149, 2 genes, copy number 8: AC104803.1, LINC00290.
- chr4:181,686,182–182,803,024, 8 genes, copy number 7 (within-gene range 3–7): AC084741.1, TEMN3-AS1, RN7SKP13, TENM3-AS1, CCNHP1, TENM3, AC108142.1, MIR1305.
- chr4:182,697,902–182,773,931, 2 genes, copy number 7 (within-gene range 3–7): AC079226.2, AC079226.1.
- chr4:183,380,345–183,517,527, 7 genes, copy number 7: AC093844.1, AC112698.1, CDKN2AIP, VTI1BP2, AC107214.1, ING2, AC107214.2.
- chr4:186,890,969–187,371,921, 9 genes, copy number 8: AC108865.1, AC108865.2, MRPS36P2, AC110772.1, AC110772.2, AC108046.1, LINC02374, AC097652.1, LINC02514.
- chr6:62,460,940–63,779,336, 19 genes, copy number 8 (within-gene range 3–8): DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3.
- chr7:45,769,105–46,481,578, 18 genes, copy number 14: GTF2IP13, RNU6-241P, CICP20, AC096582.1, AC096582.2, RNU6-326P, CCDC201, IGFBP1, IGFBP3, AC073115.2, AC073115.1, FTLP15, TTC4P1, ZNF619P1, AC023669.1, AC023669.2, AC004869.2, AC004869.1.
- chr7:51,849,086–57,837,046, 176 genes, copy number 12–33 (broad region; genes not listed).
- chr8:113,376,669–118,622,112, 32 genes, copy number 7–21: AC107890.1, AC055788.2, AC055788.1, AC103993.1, Y_RNA, AC064802.1, AC025881.1, CARS1P2, TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16, EXT1, SAMD12, AC023590.1.
- chr8:125,348,196–129,683,770, 54 genes, copy number 12–29 (within-gene range 3–29): AC084083.1, TRIB1, AC091114.1, AC016074.2, AC016074.1, LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686.
- chr11:81,821,272–82,718,299, 1 gene, copy number 15 (within-gene range 2–15): MIR4300HG.
- chr11:81,970,994–81,987,813, 1 gene, copy number 15: AP002802.1.

Autosomal genes at a single copy (total copy number 1): 1,432. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
